Somatic mutation profile of tumor specimen TCGA-VS-A957-01A (aliquot TCGA-VS-A957-01A-11D-A42O-09) from TCGA case TCGA-VS-A957, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 64.6 years (23,585 days).
Specimen TCGA-VS-A957-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72bf10c7-5be4-49e4-bcbd-ae1236ed199f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A957-10A (Blood Derived Normal), aliquot TCGA-VS-A957-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef0d2603-e650-4357-bd99-63267a5fe2c5

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, In Frame Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG13 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99322109; called by muse, mutect2, varscan2
- BAIAP3 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs780577265, COSV50103566; called by muse, mutect2, varscan2
- BCL10 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1557784897, COSV65353853; called by muse, mutect2, varscan2
- CDKL5 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101184284; called by muse, mutect2, varscan2
- CEMIP | c.1298G>A p.W433* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99586650; called by muse, mutect2, varscan2
- CSMD1 | c.7016C>T p.P2339L (on ENST00000520002; = p.P2338L on NM_033225.6) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs990309909, COSV100147072; called by muse, mutect2, varscan2
- CSMD1 | c.3309C>T p.A1103= (on ENST00000520002; = p.A1102= on NM_033225.6) | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as rs201991473; called by muse, mutect2, varscan2
- CYP27B1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs376304260, CM126947, COSV99141555; called by muse, mutect2, varscan2
- DAZAP2 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101199392; called by muse, mutect2
- DIDO1 | c.6452G>A p.R2151Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV99825666; called by muse, mutect2, varscan2
- DIP2B | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1443278274, COSV99998401; called by muse, mutect2, varscan2
- DLGAP4 | c.2857C>T p.R953C (on ENST00000339266 / NM_001365621.1; = p.R950C on NM_014902.6) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs774529250, COSV59420905; called by muse, mutect2, varscan2
- DNAH17 | c.11593T>C p.S3865P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101102160; called by muse, mutect2, varscan2
- EP400 | c.6037G>A p.D2013N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.274); catalogued as COSV100201123; called by muse, mutect2, varscan2
- EXPH5 | c.4811A>G p.K1604R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV99761522; called by muse, mutect2, varscan2
- FAM81B | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs148381850, COSV51986553; called by muse, mutect2, varscan2
- FHOD1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV99264068; called by muse, mutect2, varscan2
- GFRA2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs375798460, COSV60778678; called by muse, mutect2, varscan2
- GGT6 | c.442G>A p.A148T (on ENST00000574154 / NM_001122890.3; = p.A116T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1164871338, COSV99625953; called by muse, mutect2, varscan2
- GSTO2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100086703; called by muse, mutect2, varscan2
- HPCAL4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65716398; called by muse, mutect2, varscan2
- ITPR2 | c.7612G>A p.G2538S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189958; called by muse, mutect2
- KDM6A | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100938113, COSV100938414; called by muse, mutect2
- KRT4 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs539298697, COSV99542875; called by mutect2, varscan2
- MAP3K5 | c.3478C>T p.R1160W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1377539210, COSV62893453; called by muse, mutect2, varscan2
- MAU2 | c.1549-1G>T p.X517_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99448642; called by muse, mutect2
- MEGF11 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1462212847, COSV99987634; called by muse, mutect2, varscan2
- MYO18B | c.5842G>T p.A1948S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV100123484; called by muse, mutect2, varscan2
- NAV3 | c.1244A>T p.D415V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV99890174; called by muse, mutect2, varscan2
- NOS1 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760598926, COSV57615895; called by muse, mutect2, varscan2
- OR2T8 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1419236581, COSV60663969; called by muse, mutect2, varscan2
- PCDHGB2 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53968414; called by muse, mutect2, varscan2
- PIGG | c.2240C>T p.P747L (on ENST00000453061 / NM_001127178.3; = p.P739L on NM_017733.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1329504961, COSV99573851; called by muse, mutect2, varscan2
- RERE | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.957); catalogued as rs766806549, COSV61940863; called by muse, mutect2, varscan2
- RHOC | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99588233; called by muse, mutect2
- RNF170 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99533729; called by muse, mutect2, varscan2
- S1PR5 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100330748; called by muse, mutect2, varscan2
- SLC26A3 | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100385012, COSV60640612; called by muse, mutect2
- SRGAP2 | c.1475C>G p.S492* (on ENST00000624873 / NM_001170637.4; = p.S493* on NM_015326.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99832764; called by muse, mutect2, varscan2
- TTN | c.70364G>C p.S23455T (on ENST00000591111; = p.S16031T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | PolyPhen probably damaging (0.991); catalogued as COSV100610352; called by muse, mutect2, varscan2
- ZNF708 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV100803090; called by muse, mutect2, varscan2
- ZRANB2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99639304; called by muse, mutect2, varscan2
- CABLES1 | c.846_848del p.X282_splice (on ENST00000256925 / NM_001100619.2; = p.X17_splice on NM_138375.2) | Splice Site (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- FBXW7 | c.2001del p.S668Vfs*39 (on ENST00000281708 / NM_001349798.2; = p.S588Vfs*39 on NM_018315.5) | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- HSFX1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STAB1 | c.2021_2023dup p.T674dup | In Frame Ins (INS) | VAF 15/22 reads (68%) | called by mutect2, pindel, varscan2
- SUPT20H | c.257del p.G86Dfs*4 (on ENST00000350612 / NM_001014286.3; = p.G87Dfs*4 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- A4GALT | c.912G>A p.L304= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99966647; called by muse, mutect2, varscan2
- ADAMTS13 | c.2607C>T p.G869= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV100747060; called by muse, mutect2, varscan2
- DCLK1 | c.693G>A p.V231= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99710855; called by muse, mutect2, varscan2
- DLGAP1 | c.186C>T p.S62= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs886110395, COSV100227377; called by muse, mutect2, varscan2
- FABP5 | c.15G>A p.Q5= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99793068; called by muse, mutect2, varscan2
- GPATCH1 | c.2742G>C p.V914= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99403979; called by muse, mutect2
- INO80E | c.52C>T p.L18= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV54229509; called by muse, mutect2, varscan2
- KALRN | c.1473C>T p.S491= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs371740285, COSV53756822; called by muse, mutect2
- PAICS | c.63C>T p.V21= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99947769; called by muse, mutect2, varscan2
- PCDHA13 | c.2025G>A p.A675= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56474821; called by muse, mutect2, varscan2
- SIPA1L2 | c.2565C>T p.I855= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99478066; called by muse, mutect2, varscan2
- SLC6A15 | c.1989G>A p.L663= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99880670; called by muse, mutect2, varscan2
- WNK3 | c.3741A>G p.G1247= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100671279; called by muse, mutect2, varscan2
- ZNF462 | c.4509T>C p.F1503= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99471631; called by muse, mutect2, varscan2
- ZNF615 | c.918T>C p.H306= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100943778; called by muse, mutect2, varscan2
- OGFOD3 | c.824-1994G>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs373893804; called by muse, mutect2, varscan2
